Somatic mutation profile of tumor specimen ALCH-ABZE-TTP1-A (aliquot ALCH-ABZE-TTP1-A-1-0-D-A49D-36) from ALCHEMIST case ALCH-ABZE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.3 years (20,568 days).
Specimen ALCH-ABZE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4400d07c-2ef2-42b4-8294-9a79cb6631ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABZE-NB1-A (Blood Derived Normal), aliquot ALCH-ABZE-NB1-A-1-0-D-A49D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ac20abc-b972-4cd2-a094-630528effd30

The open-access MAF lists 39 somatic variants for this specimen: 28 protein-altering or splice-affecting, 4 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Intron 4, Silent 4, RNA 2, Nonsense Mutation 1, 5'Flank 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 130/706 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as rs876660825, CM161004, COSV52664064, COSV52987047, COSV53313892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABHD16A | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 14/502 reads (3%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.644); catalogued as rs769320532; called by muse, mutect2
- CLDN18 | c.148T>C p.W50R | Missense Mutation (SNP) | VAF 104/647 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374173675; called by muse, mutect2, varscan2
- CYLC2 | c.422C>G p.S141* | Nonsense Mutation (SNP) | VAF 30/203 reads (15%) | catalogued as COSV66337654; called by muse, mutect2, varscan2
- KNOP1 | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 101/609 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs757928834, COSV54926546; called by muse, mutect2, varscan2
- MYH14 | c.4142G>A p.R1381H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as rs188682445; called by muse, mutect2, varscan2
- OTC | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 23/796 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV99234145; called by muse, mutect2
- PANK2 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 29/499 reads (6%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV57253857; called by muse, mutect2
- RCL1 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 38/444 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749236425, COSV101099354, COSV67754236; called by muse, mutect2
- SCAP | c.2692C>T p.R898W | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs997089172, COSV99650601; called by muse, mutect2
- SCRT2 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 118/745 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs756968855, COSV55730612; called by muse, mutect2, varscan2
- SEMA4F | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as rs747799198; called by muse, mutect2, varscan2
- TXNRD1 | c.320T>A p.L107Q (on ENST00000525566 / NM_001093771.3; = p.L9Q on NM_003330.4) | Missense Mutation (SNP) | VAF 92/394 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV61598680; called by muse, mutect2, varscan2
- ANKRD11 | c.-60G>C | Splice Region (SNP) | VAF 50/317 reads (16%) | called by muse, mutect2, varscan2
- CASK | c.875T>G p.V292G | Missense Mutation (SNP) | VAF 87/706 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD3E | c.521-1G>T p.X174_splice | Splice Site (SNP) | VAF 90/665 reads (14%) | called by muse, mutect2, varscan2
- CTNNAL1 | c.1700A>C p.K567T | Missense Mutation (SNP) | VAF 66/292 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- DENND2D | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 63/458 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LDB3 | c.11G>C p.S4T | Missense Mutation (SNP) | VAF 79/606 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- MCC | c.560A>C p.K187T | Missense Mutation (SNP) | VAF 97/575 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- MGME1 | c.542A>G p.E181G | Missense Mutation (SNP) | VAF 89/435 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- MINAR1 | c.1927C>A p.Q643K | Missense Mutation (SNP) | VAF 13/318 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2
- MMS19 | c.2214G>C p.M738I | Missense Mutation (SNP) | VAF 36/316 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RANBP2 | c.2650A>T p.N884Y | Missense Mutation (SNP) | VAF 77/804 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPS6KC1 | c.1196C>T p.S399L | Missense Mutation (SNP) | VAF 90/587 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- SEPHS2 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 19/271 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.3); called by muse, mutect2
- TBX21 | c.1103G>T p.R368L | Missense Mutation (SNP) | VAF 104/702 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TCFL5 | c.147G>A p.M49I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CPEB1 | c.1533C>T p.N511= (on ENST00000617958; = p.N446= on NM_030594.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/477 reads (9%) | catalogued as rs752859272, COSV55620945; called by muse, mutect2
- IL12RB1 | c.1008C>T p.A336= | Silent (SNP) | VAF 60/386 reads (16%) | catalogued as rs201734902, CX034635, COSV100442847, COSV59096310; called by muse, mutect2, varscan2
- INTS6L | c.27C>T p.D9= | Silent (SNP) | VAF 6/151 reads (4%) | called by muse, mutect2
- SNAPC1 | c.381G>A p.R127= | Silent (SNP) | VAF 28/158 reads (18%) | called by muse, varscan2
- CCNY | c.264+13G>T | Intron (SNP) | VAF 23/324 reads (7%) | called by muse, mutect2
- EAPP | c.74+214C>T | Intron (SNP) | VAF 38/216 reads (18%) | called by muse, mutect2, varscan2
- MIR196A1 | n.47A>G | RNA (SNP) | VAF 86/537 reads (16%) | catalogued as rs556956624; called by muse, mutect2, varscan2
- OXCT1 | c.1420-31G>A | Intron (SNP) | VAF 60/808 reads (7%) | catalogued as rs375883294; called by muse, mutect2
- PHYH | chr10:13300079 C>T | 5'Flank (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- SSPOP | n.13125C>T | RNA (SNP) | VAF 41/408 reads (10%) | called by muse, mutect2, varscan2
- WHRN | c.1167-79C>G | Intron (SNP) | VAF 104/565 reads (18%) | called by muse, mutect2, varscan2
